Gene-level copy-number profile of tumor specimen TCGA-30-1718-01A from TCGA case TCGA-30-1718, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 44.9 years (16,400 days).
Specimen TCGA-30-1718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eb5ed8b0-d282-45c0-b673-c2822ddff885.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1718-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57bdf935-2439-43b9-92c1-b79850ae9215

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 234; copy number 2: 2,867; copy number 3: 8,424; copy number 4: 13,341; copy number 5: 9,903; copy number 6: 9,800; copy number 7: 9,452; copy number 8: 2,744; copy number 9: 1,409; copy number 10: 1,270; copy number 11: 351; copy number 12: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1718-01A-01D-0559-01): tumor purity 0.59, ploidy 5.1, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,042 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,636,877–76,637,339, 1 gene, copy number 11: AC104458.1.
- chr1:170,532,131–173,207,331, 57 genes, copy number 9: GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4.
- chr1:198,949,016–206,464,443, 218 genes, copy number 9 (broad region; genes not listed).
- chr1:206,474,803–206,474,864, 1 gene, copy number 9: MIR6769B.
- chr2:100,104,919–103,176,260, 60 genes, copy number 10: AC092667.1, LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1.
- chr2:119,544,432–131,047,263, 202 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr2:185,950,469–187,003,377, 14 genes, copy number 9: AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7.
- chr4:29,748,757–31,146,805, 8 genes, copy number 9 (within-gene range 8–9): EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43.
- chr5:58,198–45,895,970, 710 genes, copy number 9–10 (broad region; genes not listed).
- chr6:18,120,440–19,144,160, 13 genes, copy number 11–12: NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1.
- chr6:23,649,496–24,002,433, 5 genes, copy number 10: AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58.
- chr6:25,632,673–29,812,696, 265 genes, copy number 9 (broad region; genes not listed).
- chr6:33,771,202–36,874,803, 96 genes, copy number 9 (broad region; genes not listed).
- chr6:55,106,460–58,438,364, 39 genes, copy number 9 (within-gene range 7–9): HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr8:103,088,796–145,066,685, 622 genes, copy number 9–11 (broad region; genes not listed).
- chr9:70,188,571–73,873,297, 44 genes, copy number 11: RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9, TRPM3, RN7SL726P, AL159990.2, AL159990.1, MIR204, PIGUP1, RPL35AP21, CEMIP2, AL671309.1, ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1.
- chr9:77,716,097–78,742,744, 10 genes, copy number 10 (within-gene range 7–10): GNAQ, AL353705.2, RN7SKP59, ASS1P3, AL353705.1, AL353705.3, CEP78, PSAT1, AL592221.1, MTND2P8.
- chr10:121,178,700–121,975,217, 13 genes, copy number 9: LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2.
- chr10:122,017,982–122,019,160, 1 gene, copy number 9: AC063960.1.
- chr13:94,436,811–109,208,005, 199 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr17:5,116,032–5,175,034, 1 gene, copy number 9 (within-gene range 3–9): USP6.
- chr17:5,179,535–6,207,269, 24 genes, copy number 9: ZNF594, AC087500.1, SCIMP, AC087500.2, RABEP1, NUP88, AC015727.1, RPAIN, AC004148.1, C1QBP, DHX33, DHX33-DT, DERL2, MIS12, AC055839.2, NLRP1, AC055839.1, AC135726.1, AC006236.1, AC007846.1, AC007846.2, WSCD1, AC104770.1, RNU6-1264P.
- chr17:39,252,663–39,877,896, 21 genes, copy number 10 (within-gene range 3–10): FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr20:38,346,482–38,962,111, 29 genes, copy number 9 (within-gene range 6–9): LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1.
- chr20:38,962,472–38,978,422, 2 genes, copy number 9: AL023803.3, NPM1P19.
- chr20:48,264,969–64,313,132, 387 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
